Surgical pathology report (de-identified scan), TCGA case TCGA-HV-AA8X, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site National Cancer Center Korea, specimen TCGA-HV-AA8X-01A (Primary Tumor).

[page 1 of 2]
CLINICAL DIAGNOSIS: Pancreas body cancer

Specimen : pancreas,

GROSS:

Specimen status: Fresh

Operation: Distal pancreatectomy

Organs: Pancreas-distal (9.0 x 5.5 x 4.5 cm)

Spleen (11.5 x 7.0 x 3.8 cm)

Stomach (0.2 x 0.2 x 0.2 cm)

Lesions:

An ill-defined solid mass (4.5 x 3.5 x 3.0 cm)

at 2.1 cm apart from proximal resection margin

Cut surface: Yellowish tan, firm and granular

Extent: Extension to peripancreatic soft tissue

Resection margin: Not involved grossly (safety margin: 2.1 cm)

Other lesions: Unremarkable

Representative sections submitted

10A-0-3

adeno carcinoma, duct NOS
8500/3

Site: pancreas body C25.1

lw
4/2/14

MICROSCOPIC:

Tumor type: Ductal adenocarcinoma

Tumor location: Pancreas (body)

Histologic grade: Moderately differentiated

Tumor size: 4.5 x 3.5 x 3.0 cm

Extent: The tumor extends into peripancreatic soft tissue

Lymphovascular invasion: Present

Perineural invasion: Present

Surgical margins:

All surgical margins are free from tumor, safety margin 2.1 cm

Lymph node metastasis: Present

DIAGNOSIS:

Pancreas, body, distal pancreatectomy:

Ductal adenocarcinoma, moderately differentiated, infiltrating

Lymph node, peripancreatic, excision:

[page 2 of 2]
Metastatic carcinoma, primary in pancreas (3/11)

Spleen, splenectomy: Congestion

No tumor present

Stomach, biopsy: Smooth muscle present

No tumor present

Source: NCI Genomic Data Commons file de576d6d-d111-41da-bb07-004ab10bdb37 (TCGA-HV-AA8X.09F4014B-A548-44EE-AA6B-B855DC99A222.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).